Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A7-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Liver Segments I, II, III and IV (2280 grams, 20 x 19 x 11 cm), separately submitted left portal lymph node (4.5 x 2.6 x 1.2 cm) and gallbladder (7.5 x 3.5 x 1 cm).

A1, A2, A3, B1, B2, C1, C2, C3, C4, C5, C6

DIAGNOSIS:

Liver, Segments I, II, III and IV, resection: Grade 3 (of 4) hepatocellular carcinoma, usual type, forming a single 18.5 x 18 x 11 cm mass. The tumor is located in Segments I, II, III and IV. The tumor invades into but not through hepatic capsule. The tumor closely approaches the surgical margin (less than 1 mm) which microscopically is uninvolved. Vascular invasion is identified, involving hepatic veins microscopically. The tumor is not encapsulated. The approximate percent of tumor necrosis is 30%. The non neoplastic liver will be assessed on permanent sections and an addendum will be issued.

Lymph node, left portal, excision: A single benign lymph node is identified.

Gallbladder, cholecystectomy: Chronic cholecystitis and cholelithiasis, a single pigment stone (0.4 cm). An adenomyoma (1.0 cm) is identified. Multiple (3) cystic duct lymph nodes are negative for tumor.

ADDENDUM:

The normal liver shows a mild nonspecific chronic inflammatory infiltrate in the portal tracts but is otherwise unremarkable. Special stains show minimal amounts of hepatic iron of doubtful clinical significance. A PAS-D is unremarkable. (Seen with Doctor ...)

105-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: Liver C22.0

Tumors/Tumor Site Discrepancy		
TISSUE Discrepancy		
Final Malignancy History		
Assess (circle):		

Source: NCI Genomic Data Commons file 8f443d7c-318a-46d8-95ef-4caf496d8118 (TCGA-DD-A3A7.B520F88D-4004-4DFA-BF8D-7CE96777C5A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).